Somatic mutation profile of tumor specimen TCGA-78-7148-01A (aliquot TCGA-78-7148-01A-11D-2036-08) from TCGA case TCGA-78-7148, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.2 years (25,990 days).
Specimen TCGA-78-7148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96a114f9-2edc-44f7-8a89-3d59cf3a75c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7148-10A (Blood Derived Normal), aliquot TCGA-78-7148-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22fc52e1-b395-4d0d-81ea-335a5a65dff3

The open-access MAF lists 231 somatic variants for this specimen: 180 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 45, Frame Shift Del 8, Nonsense Mutation 7, Splice Site 5, Intron 3, 5'Flank 2, Translation Start Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABTB1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs375653991; called by muse, mutect2, varscan2
- ACAN | c.2917C>A p.L973I | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.279); catalogued as rs1277831540; called by muse, varscan2
- ACTN2 | c.1055T>A p.L352Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392451735, COSV63976514; called by muse, mutect2, varscan2
- AGBL1 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV69804454; called by muse, mutect2, varscan2
- AIF1L | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 96/242 reads (40%) | catalogued as COSV55990533; called by muse, mutect2, varscan2
- AKAP13 | c.1481G>T p.W494L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63463548; called by muse, mutect2, varscan2
- AMPH | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391062409, COSV57748367; called by muse, mutect2, varscan2
- ARMH3 | c.670-2A>T p.X224_splice | Splice Site (SNP) | VAF 5/76 reads (7%) | catalogued as COSV64236287; called by muse, mutect2
- ART5 | c.257del p.P86Lfs*9 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as COSV51707195; called by mutect2, pindel, varscan2
- ASXL3 | c.3955G>T p.D1319Y | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as rs755541299, COSV52471720, COSV52481925; called by muse, mutect2, varscan2
- BCAN | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs1465520549, COSV61257861; called by muse, mutect2
- BICRA | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV67605440; called by muse, mutect2, varscan2
- C3 | c.1216G>C p.V406L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55576057; called by muse, mutect2, varscan2
- CALHM2 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53296714; called by muse, mutect2
- CAND2 | c.1114G>C p.D372H (on ENST00000456430 / NM_001162499.2; = p.D279H on NM_012298.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs750521408, COSV55991872; called by muse, mutect2, varscan2
- CCDC144A | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1195350452, COSV61403988; called by muse, varscan2
- CCT7 | c.5T>A p.M2K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV57820636; called by muse, mutect2, varscan2
- CDH18 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV56938265; called by muse, mutect2
- CDH19 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50965128; called by muse, mutect2, varscan2
- CDH22 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV64838456; called by muse, mutect2, varscan2
- CDH26 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV54849828; called by muse, mutect2
- CDKN2A | c.44_45insTC p.W15Cfs*12 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | catalogued as COSV100446725; called by mutect2, pindel, varscan2
- CELA1 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99530142; called by muse, mutect2, varscan2
- CENPE | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54384208; called by muse, mutect2, varscan2
- CHCHD6 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52065394; called by muse, mutect2, varscan2
- CHRNB4 | c.1295G>A p.S432N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV55716901; called by muse, mutect2, varscan2
- CMYA5 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV71407373, COSV71408583; called by muse, mutect2
- CNOT3 | c.1660T>C p.S554P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV55365521; called by muse, mutect2, varscan2
- CNTNAP2 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV62213644; called by muse, mutect2, varscan2
- COL4A6 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.85); PolyPhen benign (0.408); catalogued as COSV57869726; called by muse, mutect2, varscan2
- CX3CL1 | c.886A>T p.T296S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV50056360; called by muse, mutect2, varscan2
- CYP11B1 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1304494959, COSV52825464, COSV52828663; called by muse, mutect2, varscan2
- CYP26B1 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV50012984; called by muse, mutect2, varscan2
- DCDC1 | c.2772A>T p.K924N (on ENST00000597505 / NM_001367979.1; = p.K31N on NM_020869.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV60304876; called by muse, mutect2, varscan2
- DCHS1 | c.5689G>T p.G1897C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV55038605; called by muse, mutect2, varscan2
- DEFB105A | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.189); catalogued as COSV100068736; called by mutect2, varscan2
- DISP3 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs528432088, COSV53831444; called by muse, mutect2, varscan2
- DLGAP3 | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52395536; called by muse, mutect2, varscan2
- EEF1A1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV58549055, COSV58550203; called by muse, mutect2, varscan2
- EIF1AX | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV65451254; called by muse, mutect2, varscan2
- ENC1 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56630328; called by muse, mutect2, varscan2
- EPHA6 | c.2210del p.G737Efs*8 (on ENST00000389672 / NM_001080448.3; = p.G129Efs*8 on NM_173655.4) | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as COSV101065312; called by mutect2, pindel, varscan2
- ERBB4 | c.3911G>T p.R1304L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61502134; called by muse, mutect2, varscan2
- EYA3 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65817098; called by muse, mutect2, varscan2
- FAM47C | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV63728274; called by muse, varscan2
- FASN | c.4889C>T p.P1630L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs779327861, COSV60757460, COSV60758917; called by muse, mutect2, varscan2
- FASN | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV60757476; called by muse, mutect2, varscan2
- FAT1 | c.10681G>T p.G3561C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71674977; called by muse, mutect2, varscan2
- FBN2 | c.4259G>T p.S1420I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV52526617; called by mutect2, varscan2
- FHOD3 | c.2662A>G p.T888A (on ENST00000359247 / NM_001281739.3; = p.T905A on NM_025135.5) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV57179142; called by muse, mutect2, varscan2
- FRMPD2 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV59720125; called by muse, mutect2, varscan2
- GABPB1 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55016142; called by muse, mutect2, varscan2
- GABRG2 | c.1239G>T p.K413N (on ENST00000361925 / NM_001375343.1; = p.K373N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV62719761; called by muse, mutect2
- GBF1 | c.241A>T p.I81F | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64146691; called by muse, mutect2, varscan2
- GPR156 | c.1578G>T p.R526S | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV59941068; called by muse, mutect2, varscan2
- GPR17 | c.866A>T p.H289L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55756098; called by muse, mutect2, varscan2
- GPR35 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60577833; called by muse, mutect2, varscan2
- GRID1 | c.2163C>G p.C721W | Missense Mutation (SNP) | VAF 66/297 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.926); catalogued as COSV60038776; called by muse, mutect2, varscan2
- GRIN2A | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58043725, COSV58051408; called by muse, mutect2, varscan2
- GRM5 | c.1228G>T p.G410W | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59614315; called by muse, mutect2, varscan2
- HBA2 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV52406729; called by muse, mutect2, varscan2
- HCN1 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100300776, COSV57512863; called by muse, mutect2, varscan2
- HIVEP1 | c.6688G>A p.E2230K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs377571560; called by muse, mutect2, varscan2
- HSPA5 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.045); catalogued as COSV52336748; called by muse, mutect2, varscan2
- IGSF9B | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs1212206028, COSV58069895; called by muse, mutect2, varscan2
- INSC | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 38/131 reads (29%) | catalogued as COSV65411184; called by muse, mutect2, varscan2
- ITGB8 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56010985; called by muse, mutect2, varscan2
- ITIH6 | c.3145C>A p.L1049M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV54491107; called by muse, mutect2, varscan2
- KCNB2 | c.2065A>T p.S689C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.427); catalogued as COSV73051338; called by muse, mutect2, varscan2
- KCNG1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65368596; called by muse, mutect2, varscan2
- KERA | c.296G>C p.W99S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57131123; called by muse, mutect2, varscan2
- KIAA0100 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66494612; called by muse, mutect2, varscan2
- LCE2B | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 45/168 reads (27%) | catalogued as COSV64227816; called by muse, mutect2, varscan2
- LCE3D | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); catalogued as COSV64230954; called by muse, mutect2
- LELP1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs200747820; called by muse, mutect2, varscan2
- LMX1A | c.665G>T p.R222M | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223966; called by muse, mutect2, varscan2
- LRRC28 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV57339601; called by muse, varscan2
- LRRTM1 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV54443877; called by muse, mutect2, varscan2
- MAP3K8 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV53920603; called by muse, mutect2, varscan2
- MEN1 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53645607; called by muse, mutect2, varscan2
- MKI67 | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV64075433; called by muse, mutect2, varscan2
- MMP19 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59452128; called by muse, mutect2
- MUC17 | c.4880G>T p.S1627I | Missense Mutation (SNP) | VAF 74/329 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60287853; called by muse, mutect2, varscan2
- MYCBP2 | c.2012A>G p.N671S (on ENST00000357337; = p.N709S on NM_015057.5) | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62027960; called by muse, mutect2, varscan2
- MYH2 | c.5224C>A p.Q1742K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV55442220; called by muse, mutect2
- MYH2 | c.3397G>T p.A1133S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV55442232; called by muse, mutect2, varscan2
- MYH3 | c.4740G>T p.K1580N | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56867093; called by muse, mutect2
- MYH7 | c.5257G>T p.E1753* | Nonsense Mutation (SNP) | VAF 54/140 reads (39%) | catalogued as CM050715, COSV62516052; called by muse, mutect2, varscan2
- N6AMT1 | c.136G>C p.V46L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.021); catalogued as COSV100375009; called by mutect2, varscan2
- NCAPD2 | c.987+1G>A p.X329_splice | Splice Site (SNP) | VAF 34/88 reads (39%) | catalogued as COSV59699416, COSV59700855; called by muse, mutect2, varscan2
- NIM1K | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as COSV58143330; called by muse, mutect2, varscan2
- NOTCH1 | c.7034G>T p.G2345V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV53068330, COSV53076713; called by muse, mutect2, varscan2
- NOTCH4 | c.3884C>T p.P1295L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1223240479, COSV66682089; called by muse, mutect2, varscan2
- NUP107 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV57495907; called by muse, mutect2, varscan2
- OCA2 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV62350896; called by muse, mutect2, varscan2
- OR4K2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1376061648, COSV53850474; called by muse, mutect2, varscan2
- OR4P4 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.37); catalogued as COSV58922761, COSV58923406; called by muse, mutect2, varscan2
- OR9G1 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56452136; called by muse, mutect2
- OSGEPL1 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.578); catalogued as COSV51463053; called by muse, mutect2, varscan2
- PCARE | c.1511C>A p.A504D | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV59055908, COSV59058207; called by muse, mutect2, varscan2
- PCDHB16 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53365949; called by muse, mutect2
- PHGDH | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65571469; called by muse, mutect2, varscan2
- PHIP | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1483092371, COSV51506934; called by muse, mutect2, varscan2
- PKP4 | c.3256G>T p.G1086C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61579337; called by muse, mutect2, varscan2
- PLXDC1 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV59552274; called by muse, mutect2, varscan2
- PLXNA4 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV58141162, COSV58152062; called by muse, mutect2, varscan2
- POP1 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV62893406; called by muse, mutect2, varscan2
- PRUNE2 | c.8416C>G p.P2806A | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317731; called by muse, mutect2, varscan2
- PTH2R | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1253351436, COSV55917735; called by muse, mutect2
- PTPRH | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as rs746108012, COSV54747387; called by muse, mutect2, varscan2
- PTPRN | c.2032T>C p.W678R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55349959; called by muse, mutect2, varscan2
- R3HCC1L | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV54403065; called by muse, mutect2, varscan2
- RAB11FIP1 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54761757; called by muse, mutect2, varscan2
- RAB6C | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs1198064010, COSV69339630; called by muse, mutect2, varscan2
- RAD54B | c.2216A>C p.D739A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60252853; called by muse, mutect2, varscan2
- RBBP8 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59094215; called by muse, mutect2, varscan2
- RBM10 | c.503-1G>A p.X168_splice | Splice Site (SNP) | VAF 22/30 reads (73%) | catalogued as COSV61309841, COSV61310211, COSV61310660; called by muse, mutect2, varscan2
- RBP3 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs1032342823; called by muse, mutect2, varscan2
- RFC1 | c.3313C>T p.Q1105* (on ENST00000381897 / NM_001363496.2; = p.Q1104* on NM_002913.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | catalogued as rs377688011; called by muse, mutect2, varscan2
- RLF | c.5416A>T p.N1806Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV65652354; called by muse, mutect2, varscan2
- RNF113B | c.476C>G p.P159R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs768653186, COSV57435453; called by muse, mutect2, varscan2
- ROBO2 | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as COSV100166873, COSV59898286, COSV59922203; called by muse, mutect2, varscan2
- RYR2 | c.12527T>C p.V4176A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV63696857; called by muse, mutect2, varscan2
- SCUBE1 | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV62614042; called by muse, mutect2, varscan2
- SEMA3D | c.2138A>G p.Y713C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52397997; called by muse, mutect2, varscan2
- SEMG2 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV65647671; called by muse, mutect2, varscan2
- SHOX | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV61861486; called by muse, mutect2, varscan2
- SIRPD | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV101064934; called by muse, mutect2, varscan2
- SLC12A6 | c.1070C>T p.A357V (on ENST00000354181 / NM_001365088.1; = p.A306V on NM_005135.2) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV51628136; called by muse, mutect2, varscan2
- SLC2A9 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53323972; called by muse, mutect2, varscan2
- SLC32A1 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.154); catalogued as COSV54147422; called by muse, mutect2, varscan2
- SLC39A12 | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66200323; called by muse, mutect2, varscan2
- SLC7A8 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758342760, COSV57554849; called by muse, mutect2, varscan2
- SLCO5A1 | c.176C>A p.P59Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.301); catalogued as COSV52662792; called by muse, mutect2, varscan2
- SMAD9 | c.1125G>T p.K375N (on ENST00000379826 / NM_001127217.3; = p.K338N on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63205541; called by muse, mutect2, varscan2
- SMARCA4 | c.3484G>T p.G1162C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2, varscan2
- SNX19 | c.1250A>T p.E417V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as COSV56286974; called by muse, mutect2, varscan2
- SPTA1 | c.6168C>G p.N2056K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63756291; called by muse, mutect2, varscan2
- SRP72 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61377705, COSV61378385; called by muse, mutect2, varscan2
- STAP1 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55326097, COSV55328738; called by muse, mutect2, varscan2
- SYCP2L | c.873G>T p.R291S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV51655071; called by muse, mutect2, varscan2
- TAF3 | c.1666A>G p.K556E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as rs1325774785, COSV60208443; called by muse, mutect2, varscan2
- TARBP1 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1430097110, COSV50191372; called by muse, mutect2, varscan2
- TBC1D2 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs759294060, COSV59786479; called by muse, mutect2, varscan2
- TBCK | c.910G>T p.D304Y (on ENST00000273980 / NM_001163436.4; = p.D241Y on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as COSV56758520; called by muse, mutect2, varscan2
- TENM2 | c.2436C>A p.D812E (on ENST00000518659 / NM_001122679.2; = p.D580E on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV69135282; called by muse, varscan2
- TEX13A | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100780596, COSV61166911; called by muse, mutect2, varscan2
- TIAM1 | c.4460A>G p.Q1487R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54560806; called by muse, mutect2, varscan2
- TMEM168 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV57181516; called by muse, mutect2, varscan2
- TMEM81 | c.36C>G p.S12R | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as rs201987281, COSV52705581; called by muse, mutect2, varscan2
- TNR | c.1160C>A p.P387Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV54897899; called by muse, mutect2, varscan2
- TNS3 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1277205150, COSV60794256; called by muse, mutect2
- TRAJ9 | c.41C>A p.T14K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs370957055; called by muse, mutect2, varscan2
- TRIM52 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1259267992, COSV59844567; called by muse, mutect2, varscan2
- UNC5C | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV71661019; called by muse, mutect2, varscan2
- USH2A | c.3129T>A p.D1043E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV56395997; called by muse, mutect2, varscan2
- USP26 | c.1609C>A p.Q537K | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV63709114; called by muse, mutect2, varscan2
- WNT10B | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56405817; called by muse, mutect2, varscan2
- XYLT1 | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV54489416; called by muse, mutect2
- ZFHX4 | c.10413C>A p.H3471Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51467412; called by muse, mutect2, varscan2
- ZNF106 | c.5221C>T p.H1741Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55518703; called by muse, mutect2, varscan2
- ZNF226 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs749470406, COSV56197212; called by muse, mutect2, varscan2
- ZNF292 | c.2257A>G p.I753V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1479480866, COSV60542283; called by muse, mutect2, varscan2
- ZNF423 | c.1947C>G p.F649L (on ENST00000563137 / NM_001379286.1; = p.F641L on NM_015069.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV52196348; called by muse, mutect2
- ZNF606 | c.1343G>C p.R448P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138065835, COSV58706909; called by muse, mutect2, varscan2
- ZNF629 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52699473; called by muse, mutect2, varscan2
- ZNRF3 | c.1760G>T p.R587L (on ENST00000544604 / NM_001206998.2; = p.R487L on NM_032173.3) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100238799, COSV60436131; called by muse, varscan2
- ZSCAN4 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100552521, COSV59000663; called by muse, mutect2, varscan2
- ZSWIM5 | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62735380; called by muse, mutect2, varscan2
- CCL23 | c.274A>T p.N92Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CSNK2A2 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.114); called by muse, mutect2
- GTDC1 | c.1247del p.Q416Rfs*10 (on ENST00000344850 / NM_001354361.1; = p.Q331Rfs*10 on NM_024659.6 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- JCAD | c.3142_3143del p.L1048Tfs*15 | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | called by mutect2, pindel, varscan2
- LRRC7 | c.1330C>T p.L444F (on ENST00000651989 / NM_001370785.2; = p.L411F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LZTS1 | c.623del p.G208Afs*17 | Frame Shift Del (DEL) | VAF 40/119 reads (34%) | called by mutect2, pindel, varscan2
- MICAL3 | c.261_264+17del p.X87_splice | Splice Site (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- PLCL1 | c.2956del p.D986Tfs*30 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- STK11 | c.794_803del p.E265Gfs*19 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- ZNF484 | c.1198_1201del p.S400Cfs*167 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- APBA1 | c.2295T>C p.N765= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV55231568; called by muse, mutect2, varscan2
- APOL5 | c.636T>C p.H212= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV50767514; called by muse, mutect2, varscan2
- ATP13A5 | c.96G>C p.R32= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV60871653; called by muse, mutect2, varscan2
- ATP9A | c.363G>T p.A121= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58768780; called by muse, mutect2
- ATRX | c.4629A>G p.E1543= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV64879521; called by muse, mutect2, varscan2
- BRSK1 | c.168G>T p.T56= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV58664398; called by muse, mutect2
- CD248 | c.1989T>C p.A663= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV60937081; called by muse, mutect2, varscan2
- DCAF8L1 | c.417G>A p.L139= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV71595383; called by muse, mutect2, varscan2
- DISP1 | c.4065T>C p.F1355= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV52661725; called by muse, mutect2, varscan2
- EML5 | c.5011A>C p.R1671= (on ENST00000380664; = p.R1679= on NM_183387.3) | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as COSV61348198; called by muse, mutect2, varscan2
- FAM181A | c.249C>T p.I83= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV50889810; called by muse, mutect2, varscan2
- GRM5 | c.1359G>T p.T453= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs369401136, COSV59614304; called by muse, mutect2, varscan2
- HAS2 | c.225A>G p.L75= | Silent (SNP) | VAF 36/231 reads (16%) | catalogued as COSV58265463; called by muse, mutect2, varscan2
- IFNL3 | c.450C>A p.R150= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV69830094; called by muse, mutect2, varscan2
- IFNL3 | c.133C>T p.L45= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV69830097; called by muse, mutect2, varscan2
- IL17RC | c.2322G>T p.A774= (on ENST00000295981 / NM_153461.4; = p.A688= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs777634372, COSV55974005; called by muse, mutect2, varscan2
- KMT2D | c.3327C>T p.A1109= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV56459983; called by muse, mutect2
- KRTAP5-9 | c.270A>T p.S90= | Silent (SNP) | VAF 145/348 reads (42%) | catalogued as COSV73200223; called by muse, mutect2, varscan2
- LAS1L | c.579G>T p.L193= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV56708023, COSV56709482; called by muse, mutect2, varscan2
- LRRC32 | c.330G>A p.A110= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs751013352, COSV52631674; called by muse, mutect2, varscan2
- LRRCC1 | c.426A>G p.L142= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV64484233; called by muse, mutect2, varscan2
- MED23 | c.1869C>T p.L623= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs768371099, COSV63434182; called by muse, mutect2, varscan2
- MROH9 | c.816C>A p.I272= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs374921240, COSV63010311; called by muse, mutect2, varscan2
- NIBAN3 | c.1377G>T p.L459= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV56311239; called by muse, mutect2
- NLRP12 | c.2058G>T p.T686= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1014676111, COSV60750244; called by muse, mutect2, varscan2
- OR6F1 | c.651C>A p.S217= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV57468499; called by muse, mutect2
- PAQR5 | c.712C>T p.L238= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV61817667; called by muse, mutect2, varscan2
- PLCE1 | c.1755C>T p.T585= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV53359343; called by muse, mutect2, varscan2
- PPP2R2B | c.381A>T p.P127= (on ENST00000394409; = p.P193= on NM_181674.2) | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV60770441; called by muse, mutect2, varscan2
- RNFT2 | c.921G>C p.L307= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs1037159494, COSV57487065, COSV99985082; called by muse, mutect2, varscan2
- RYR3 | c.5847G>A p.E1949= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV66799206; called by muse, mutect2, varscan2
- SCN11A | c.2388G>T p.V796= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100181043, COSV56573505; called by muse, mutect2, varscan2
- SCUBE1 | c.1740C>A p.A580= | Silent (SNP) | VAF 70/151 reads (46%) | catalogued as rs752275627, COSV62614036; called by muse, mutect2, varscan2
- SHANK3 | c.4545G>T p.L1515= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV53188382; called by muse, mutect2, varscan2
- SI | c.3987T>C p.I1329= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV52287762; called by muse, mutect2, varscan2
- SIRPD | c.399G>T p.R133= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV101064933; called by muse, mutect2, varscan2
- SLC16A1 | c.582C>T p.L194= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV63709754; called by muse, mutect2, varscan2
- SLC8A3 | c.270G>A p.G90= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV63523329; called by muse, mutect2
- SSH1 | c.2451G>A p.Q817= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV58457944; called by muse, mutect2, varscan2
- SUGCT | c.540G>C p.S180= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV59327877, COSV59339955; called by muse, mutect2, varscan2
- TBC1D3B | c.1116T>C p.P372= | Silent (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- TEX11 | c.1360C>T p.L454= (on ENST00000344304; = p.L439= on NM_031276.3) | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs148392671, COSV60233885; called by muse, mutect2, varscan2
- TSPOAP1 | c.1026G>T p.S342= | Silent (SNP) | VAF 14/185 reads (8%) | catalogued as COSV52112454; called by muse, mutect2
- VPS13B | c.8277G>A p.R2759= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV62148609; called by muse, mutect2, varscan2
- XIRP2 | c.324A>G p.R108= (on ENST00000628543; = p.R283= on NM_152381.6) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1426435720, COSV54714382; called by muse, mutect2
- AP000769.5 | chr11:65499108 del CAGA | 5'Flank (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel
- ASPDH | chr19:50514491 C>T | 5'Flank (SNP) | VAF 54/171 reads (32%) | catalogued as COSV100975957; called by muse, mutect2, varscan2
- DCX | c.-22-365C>T | Intron (SNP) | VAF 12/119 reads (10%) | catalogued as COSV57571817; called by muse, mutect2, varscan2
- DNAH14 | c.1032+132A>C | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100835913; called by muse, mutect2, varscan2
- DST | c.4297-4440C>G | Intron (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99757371; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120914 G>T | 3'Flank (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
